Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A1MN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A1MN-01A (Primary Tumor).

1CD-0-3

Carcinoma, squamous cell, keratinizing, NOS
Site: cervix, NOS C53.9 2/24/11 8071/3
lw

Patient Name: [REDACTED]

DOB: [REDACTED]

Accession: [REDACTED]

MRN: [REDACTED]

PAN: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F

DOB: [REDACTED]

Service: Gynecology

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED]

M.D.

Other Related Clinical Data:

DIAGNOSIS:

UTERUS, CERVIX, BIOPSY

- INVASIVE, MODERATELY DIFFERENTIATED, KERATINIZING SQUAMOUS CELL CARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

M.D.

***Report Electronically Reviewed and Signed Out By [REDACTED]

M.D.***

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis. (D [REDACTED])

M.D.

History:

The patient is a [REDACTED] year old woman with a history of cervical cancer. Operative procedure: Examination under anesthesia, cervical biopsy.

Specimen(s) Received:

A: CERVIX

Gross Description

The specimen is received in a formalin-filled container labeled [REDACTED] and "cervical biopsy." It consists of irregular, gray-white tissue fragments admixed with blood clot, aggregating to 3.5 x 1.5 x 0.4 cm. Labeled A1 and A2. Jar 0.

The performance characteristics of some immunohistochemical stains, fluorescence in-situ hybridization tests and immunophenotyping by flow cytometry cited in this report (if any) were determined by the Surgical Pathology Department at [REDACTED] as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the Clinical Laboratory Improvement Act of 1988 (CLIA '88). Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the US Food and Drug Administration. Such diagnostic tests may

Printed from [REDACTED]

HIFAA Discrepancy		X

Source: NCI Genomic Data Commons file c615358a-14cb-4b2a-a5d4-4e73b1298aad (TCGA-C5-A1MN.8C677406-F68A-429E-BC9A-9AE26928D226.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).